Somatic mutation profile of tumor specimen ALCH-AEFA-TTP1-A (aliquot ALCH-AEFA-TTP1-A-1-0-D-A618-36) from ALCHEMIST case ALCH-AEFA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,556 days).
Specimen ALCH-AEFA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bba03803-0c65-491b-a8d4-1d5f8a3f9377.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEFA-NB1-A (Blood Derived Normal), aliquot ALCH-AEFA-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f873e31c-791a-43fc-8420-a80dcf0ee0c7

The open-access MAF lists 387 somatic variants for this specimen: 250 protein-altering or splice-affecting, 77 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 208, Silent 77, Nonsense Mutation 27, Intron 25, 3'UTR 10, RNA 10, 5'Flank 8, 5'UTR 5, Frame Shift Del 5, Splice Site 4, Splice Region 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 57/433 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.697C>G p.P233A | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763496386; called by muse, mutect2, varscan2
- AGAP6 | c.1700A>T p.Q567L (on ENST00000374056 / NM_001365867.1; = p.Q590L on NM_001077665.2) | Missense Mutation (SNP) | VAF 31/652 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV65017426; called by muse, mutect2
- AHNAK2 | c.10685C>A p.P3562H | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372078377; called by muse, mutect2, varscan2
- AK9 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.178); catalogued as rs780627284; called by muse, mutect2, varscan2
- ANKRD30B | c.2518C>A p.Q840K | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV57704827; called by muse, mutect2
- ANKRD36 | c.3295-1G>C p.X1099_splice | Splice Site (SNP) | VAF 27/109 reads (25%) | catalogued as COSV70401136; called by muse, mutect2, varscan2
- AQP12B | c.333G>T p.Q111H (on ENST00000621682; = p.Q123H on NM_001102467.2) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV68184032; called by mutect2, varscan2
- ATM | c.5369A>T p.D1790V | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs746945284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B3 | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59544887; called by muse, mutect2, varscan2
- ATR | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 33/276 reads (12%) | catalogued as COSV63391188; called by muse, mutect2, varscan2
- CACNA1C | c.894C>A p.C298* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as rs1555658742; called by muse, mutect2, varscan2
- CCDC168 | c.1703G>A p.G568D | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs1034011422; called by muse, mutect2, varscan2
- COL11A1 | c.3399G>T p.E1133D | Missense Mutation (SNP) | VAF 32/542 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.152); catalogued as COSV62189938; called by muse, mutect2
- CSMD3 | c.2531G>T p.R844L (on ENST00000297405 / NM_001363185.1; = p.R740L on NM_052900.3) | Missense Mutation (SNP) | VAF 50/305 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); catalogued as COSV52330132; called by muse, varscan2
- DNAH10 | c.4609-1G>T p.X1537_splice (on ENST00000409039; = p.X1476_splice on NM_207437.3) | Splice Site (SNP) | VAF 8/140 reads (6%) | catalogued as COSV68991670; called by muse, mutect2
- DPP6 | c.1228C>A p.L410I (on ENST00000377770 / NM_001364500.2; = p.L348I on NM_001936.5) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as COSV100127976; called by muse, mutect2, varscan2
- DUXA | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 21/295 reads (7%) | catalogued as COSV73729743; called by muse, mutect2
- EEF1A2 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV53204641; called by muse, mutect2, varscan2
- EVX2 | c.1115C>A p.S372* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100420808, COSV57964902; called by muse, mutect2
- FBXL16 | c.1100T>A p.V367E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV60964928; called by muse, mutect2, varscan2
- FLNC | c.3368C>A p.P1123H | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57953793; called by muse, mutect2, varscan2
- FLRT2 | c.335G>T p.R112I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV58145669; called by muse, mutect2
- GDA | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs1199979505; called by muse, mutect2
- GLT1D1 | c.99C>A p.C33* | Nonsense Mutation (SNP) | VAF 17/220 reads (8%) | catalogued as COSV55887378; called by muse, mutect2
- GSDMC | c.939G>T p.W313C | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.275); catalogued as COSV52695798; called by muse, mutect2
- HYDIN | c.4548G>T p.R1516S | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV66870554; called by muse, mutect2, varscan2
- HYDIN | c.4547G>T p.R1516M | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV66882797; called by muse, mutect2, varscan2
- ITGA8 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65233679; called by muse, mutect2
- KCNK2 | c.1281G>T p.*427Yext*4 (on ENST00000444842 / NM_001017425.3; = p.*412Yext*4 on NM_014217.4) | Nonstop Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV67207390; called by muse, mutect2, varscan2
- KCNU1 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 39/262 reads (15%) | catalogued as COSV67753929; called by muse, mutect2, varscan2
- KCNV1 | c.1479del p.S493Rfs*22 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as COSV52086625; called by mutect2, pindel
- KLHL24 | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV104387311; called by muse, mutect2
- KRT71 | c.383C>A p.A128D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV57293216; called by muse, mutect2, varscan2
- LILRA4 | c.17C>A p.T6K | Missense Mutation (SNP) | VAF 9/261 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); catalogued as rs200178658; called by muse, mutect2
- LRP2 | c.1870G>T p.V624L | Missense Mutation (SNP) | VAF 82/477 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV55543941; called by muse, mutect2, varscan2
- MACF1 | c.8789A>G p.Q2930R | Missense Mutation (SNP) | VAF 14/160 reads (9%) | catalogued as rs1170657383; called by muse, mutect2
- MAGEB6B | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as rs771424539; called by muse, mutect2
- MAP2K3 | c.723C>A p.N241K (on ENST00000342679 / NM_145109.3; = p.N212K on NM_002756.4) | Missense Mutation (SNP) | VAF 17/494 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.742); catalogued as COSV57566617; called by muse, mutect2
- MKRN3 | c.1333C>A p.L445I | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1234915933; called by muse, mutect2
- MRPS35 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762062628, COSV50011197, COSV50012641; called by muse, mutect2
- NAV3 | c.4654G>T p.V1552L | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV57113223; called by muse, mutect2, varscan2
- NBEA | c.2745G>C p.M915I | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1280802959, COSV59813708; called by muse, mutect2, varscan2
- NLRP9 | c.1622C>A p.A541D | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV60462197; called by muse, mutect2, varscan2
- NOX1 | c.1263C>A p.F421L | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV54193806; called by muse, mutect2, varscan2
- OPRL1 | c.992G>C p.R331P | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV61090915; called by muse, mutect2
- OR12D3 | c.827T>C p.M276T | Missense Mutation (SNP) | VAF 21/376 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs150773982; called by muse, mutect2
- OR2T34 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs781206843; called by muse, mutect2, varscan2
- OR52N2 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1328631788; called by muse, mutect2, varscan2
- OR9G1 | c.245T>G p.V82G | Missense Mutation (SNP) | VAF 34/578 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV56451425; called by muse, mutect2
- PCDH11X | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 42/610 reads (7%) | catalogued as COSV100009348; called by muse, mutect2
- PCDHB2 | c.1622C>A p.P541Q | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781891345; called by muse, mutect2, varscan2
- PDCL2 | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as COSV55259804, COSV55261512; called by muse, mutect2
- PECR | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767429439, COSV54736136; called by muse, mutect2
- PTCH2 | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1193629202, COSV64712016; called by muse, mutect2
- PTER | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs754323377; called by muse, mutect2
- QDPR | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM155931; called by muse, mutect2
- RYR1 | c.10919C>T p.P3640L | Missense Mutation (SNP) | VAF 49/355 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100615818; called by muse, mutect2, varscan2
- SH2D1B | c.19C>A p.H7N | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63392982; called by muse, mutect2, varscan2
- SI | c.2848G>T p.A950S | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as COSV52271172; called by muse, mutect2, varscan2
- SLC8A1 | c.1954G>T p.G652* | Nonsense Mutation (SNP) | VAF 44/280 reads (16%) | catalogued as COSV100245182; called by muse, mutect2, varscan2
- SORCS3 | c.2115C>G p.H705Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.041); catalogued as COSV63798027; called by muse, mutect2, varscan2
- SPTBN4 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs781452073; called by muse, mutect2
- ST6GALNAC2 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | PolyPhen benign (0.141); catalogued as rs868827611; called by muse, mutect2, varscan2
- STK11IP | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1427377138; called by muse, mutect2
- THEMIS | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs756380182, COSV64069004; called by muse, mutect2, varscan2
- TP53 | c.472del p.R158Afs*12 | Frame Shift Del (DEL) | VAF 19/163 reads (12%) | catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by mutect2, pindel, varscan2
- TREM2 | c.55del p.H19Tfs*23 | Frame Shift Del (DEL) | VAF 32/257 reads (12%) | catalogued as COSV100632631; called by mutect2, pindel, varscan2
- UBE3B | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751045596; called by muse, mutect2, varscan2
- ZFPM1 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV60323255; called by muse, mutect2
- ZNF34 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs369632583; called by muse, mutect2
- ZNF728 | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV101655342; called by muse, mutect2, varscan2
- ABCC8 | c.3428G>A p.S1143N | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- AC242842.3 | c.5323+1G>T p.X1775_splice | Splice Site (SNP) | VAF 39/552 reads (7%) | called by muse, mutect2
- ACP6 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ALS2CL | c.2596G>A p.G866S | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2
- ANK3 | c.8712A>T p.E2904D | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ARMCX5 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASB1 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 31/133 reads (23%) | called by muse, mutect2, varscan2
- ASCC3 | c.6163G>T p.E2055* | Nonsense Mutation (SNP) | VAF 80/559 reads (14%) | called by muse, mutect2, varscan2
- ASXL1 | c.1660A>T p.S554C | Missense Mutation (SNP) | VAF 30/609 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2
- BCLAF3 | c.146G>T p.W49L | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2
- BCORL1 | c.4549C>A p.L1517M | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BOLL | c.795G>T p.M265I | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- BTAF1 | c.191A>T p.Q64L | Missense Mutation (SNP) | VAF 24/401 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2
- C2CD3 | c.382A>T p.R128* | Nonsense Mutation (SNP) | VAF 48/223 reads (22%) | called by muse, mutect2, varscan2
- CACNA1C | c.5045C>A p.A1682D | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPN5 | c.843G>T p.E281D (on ENST00000456580; = p.E241D on NM_004055.5) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2
- CCDC40 | c.3105A>T p.E1035D | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDHR2 | c.2126C>A p.P709Q | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.307); called by muse, mutect2
- CFH | c.2891G>T p.G964V | Missense Mutation (SNP) | VAF 79/512 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.73); called by muse, varscan2
- CGREF1 | c.339C>A p.N113K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by mutect2, varscan2
- CHM | c.220G>C p.V74L | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2
- CHORDC1 | c.201G>C p.E67D | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CNTN1 | c.2205C>A p.H735Q | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2
- COL11A1 | c.3107G>T p.G1036V | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL4A1 | c.3478G>T p.G1160W | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A6 | c.1813G>T p.G605* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- COL6A5 | c.2975G>T p.C992F | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CPD | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- CYP2C19 | c.1197A>T p.K399N | Missense Mutation (SNP) | VAF 16/325 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2
- DCST1 | c.1467C>A p.H489Q | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- DDX60L | c.3134A>T p.K1045M | Missense Mutation (SNP) | VAF 25/267 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); called by muse, mutect2
- DENND1A | c.2252G>T p.G751V | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2
- DIO3 | c.626C>G p.T209S | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.93); called by muse, mutect2
- DLL4 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH1 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); called by muse, mutect2
- DNAJC6 | c.2152A>G p.M718V | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.021); called by muse, mutect2
- DNM1 | c.1765T>A p.F589I | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- DPYSL3 | c.1441C>A p.R481S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- DYDC1 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2
- DYNC2H1 | c.8576A>G p.H2859R | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- EHD3 | c.347T>A p.V116E | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- EN2 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.327); called by muse, mutect2
- ENO4 | c.311T>C p.V104A (on ENST00000622726; = p.V103A on NM_001242699.2) | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.112); called by muse, mutect2
- ETNPPL | c.1083-1G>A p.X361_splice | Splice Site (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
- ETV4 | c.256+3G>C | Splice Region (SNP) | VAF 24/248 reads (10%) | called by muse, mutect2
- FAM217B | c.620G>T p.R207M | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAM25A | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2
- FAT3 | c.3266G>C p.G1089A | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, varscan2
- FCAR | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- FERD3L | c.415C>G p.R139G | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- FERD3L | c.287G>T p.R96M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- FIBIN | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- FIBP | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FNDC1 | c.4156G>T p.G1386* | Nonsense Mutation (SNP) | VAF 46/281 reads (16%) | called by muse, mutect2, varscan2
- FRG2C | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.959); called by muse, mutect2
- FRMPD3 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 65/327 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GCA | c.524T>C p.F175S | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GFY | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- GLRX3 | c.668A>T p.E223V | Missense Mutation (SNP) | VAF 22/281 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- GMEB1 | c.1330C>G p.Q444E | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2
- GPR50 | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- GPRASP1 | c.4115T>A p.V1372D | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- GRIK3 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.352); called by muse, mutect2
- HEPHL1 | c.3033C>A p.S1011R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HERC2 | c.12121A>G p.K4041E | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2
- HNRNPH1 | c.14C>G p.T5R | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.62); called by muse, mutect2
- HNRNPH2 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2
- HNRNPL | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- HP1BP3 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 25/382 reads (7%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.866); called by muse, mutect2
- HTR1F | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF8 | c.522G>T p.M174I | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- INSYN2B | c.772T>C p.C258R | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); called by muse, mutect2
- ITGB4 | c.2755G>T p.G919C | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNA1 | c.1151G>C p.G384A | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KIAA2012 | c.3368C>A p.A1123D | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF16B | c.113T>C p.L38S | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); called by muse, mutect2
- KIF19 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KISS1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KLHL15 | c.924G>T p.W308C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.845); called by muse, mutect2
- KLK4 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- KRTAP9-3 | c.213C>A p.C71* | Nonsense Mutation (SNP) | VAF 18/342 reads (5%) | called by muse, mutect2
- LARS1 | c.677G>C p.R226T (on ENST00000394434 / NM_020117.11; = p.R199T on NM_016460.3) | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2
- LEMD2 | c.1476G>C p.W492C | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LINS1 | c.1388T>A p.L463Q | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- LRP1B | c.10709G>A p.W3570* | Nonsense Mutation (SNP) | VAF 90/541 reads (17%) | called by muse, mutect2, varscan2
- LUZP2 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED1 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2, varscan2
- MEP1B | c.2057T>A p.M686K | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2
- MMGT1 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MPDZ | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- MROH9 | c.2469dup p.L824Ifs*3 | Frame Shift Ins (INS) | VAF 69/438 reads (16%) | called by mutect2, pindel, varscan2
- MUC16 | c.31153T>A p.S10385T | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.3); called by muse, mutect2
- MYO1A | c.1618C>A p.H540N | Missense Mutation (SNP) | VAF 46/465 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- N4BP1 | c.2192A>T p.E731V | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NIBAN1 | c.1931G>T p.G644V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- NIT2 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP13 | c.2617G>T p.E873* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- NOX5 | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NSUN3 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NUP205 | c.3287A>T p.Q1096L | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- OR10J5 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 35/161 reads (22%) | called by muse, mutect2, varscan2
- OR13F1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2
- OR14A16 | c.575T>A p.I192K | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.425); called by muse, mutect2
- OR2H1 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 54/529 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- OR2M2 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2
- OR51C1P | c.777del p.I260Lfs*16 | Frame Shift Del (DEL) | VAF 20/131 reads (15%) | called by mutect2, pindel, varscan2
- OR52R1 | c.535del p.Q179Sfs*10 | Frame Shift Del (DEL) | VAF 19/216 reads (9%) | called by pindel, varscan2*
- PAK3 | c.875G>T p.G292V (on ENST00000262836 / NM_001324328.2; = p.G277V on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/376 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- PARD6B | c.869A>T p.D290V | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PCDHB10 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 54/359 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB2 | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDE3B | c.1796G>T p.S599I | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PDE4DIP | c.4098G>T p.Q1366H | Missense Mutation (SNP) | VAF 80/621 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PDE6C | c.1528C>A p.R510S | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- PEX5 | c.1330G>T p.E444* (on ENST00000420616; = p.E436* on NM_000319.5) | Nonsense Mutation (SNP) | VAF 27/408 reads (7%) | called by muse, mutect2
- PHF2 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- PIK3R4 | c.3292G>T p.V1098F | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- PKP2 | c.1573C>T p.L525F | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PLCE1 | c.4058T>G p.F1353C | Missense Mutation (SNP) | VAF 27/462 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLOD2 | c.819G>T p.W273C | Missense Mutation (SNP) | VAF 39/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPFIA2 | c.3019T>C p.C1007R | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, varscan2
- PPP1R16B | c.1486C>A p.P496T | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2
- PPP3R2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, varscan2
- PRH1 | c.292G>T p.G98* | Nonsense Mutation (SNP) | VAF 36/318 reads (11%) | called by muse, varscan2
- PRKCSH | c.*16+8G>T | Splice Region (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- PTPRT | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- RELN | c.7667G>C p.G2556A | Missense Mutation (SNP) | VAF 76/481 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- RENBP | c.972G>A p.W324* | Nonsense Mutation (SNP) | VAF 7/173 reads (4%) | called by muse, mutect2
- ROBO1 | c.782G>T p.R261I | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ROCK2 | c.1474A>T p.K492* | Nonsense Mutation (SNP) | VAF 40/191 reads (21%) | called by muse, mutect2, varscan2
- RPL36A | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2
- RPS6KA6 | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- RUBCN | c.2646+4A>T | Splice Region (SNP) | VAF 30/309 reads (10%) | called by muse, mutect2
- SCG2 | c.1188G>T p.E396D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SCNN1B | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SENP6 | c.2237G>T p.R746L | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SI | c.2847G>C p.L949F | Missense Mutation (SNP) | VAF 32/307 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC22A14 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SLC27A6 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2
- SLITRK6 | c.1573C>A p.L525M | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- SMG1 | c.8090C>T p.P2697L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- SMO | c.2179C>A p.Q727K | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31A6 | c.1017C>A p.N339K | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); called by mutect2, varscan2
- SPATA31E1 | c.3653G>T p.R1218M | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); called by muse, mutect2
- ST3GAL4 | c.179G>T p.G60V (on ENST00000392669 / NM_001254758.1; = p.G56V on NM_006278.3) | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SYCP2L | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, varscan2
- SYNE1 | c.20463G>C p.W6821C (on ENST00000367255 / NM_182961.4; = p.W6750C on NM_033071.3) | Missense Mutation (SNP) | VAF 68/567 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYTL4 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.312); called by muse, varscan2
- TAF3 | c.1424G>T p.R475L | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBC1D8B | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBCEL | c.682A>T p.N228Y | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- TEP1 | c.5515G>T p.G1839W | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TEX13C | c.1127G>T p.S376I | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- TEX55 | c.1072G>T p.D358Y | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- TFPI | c.831A>T p.K277N | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, varscan2
- THSD7A | c.2521C>A p.R841S | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TIE1 | c.3119G>A p.G1040E | Missense Mutation (SNP) | VAF 21/339 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMC1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 38/441 reads (9%) | called by muse, mutect2
- TMPRSS11A | c.551C>A p.P184Q | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- TMPRSS11A | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2
- TPR | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 62/375 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- TRAF2 | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- TRPS1 | c.1507A>G p.S503G (on ENST00000220888 / NM_001330599.2; = p.S516G on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/376 reads (12%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBA6 | c.2809G>T p.E937* | Nonsense Mutation (SNP) | VAF 7/133 reads (5%) | called by muse, mutect2
- UNC80 | c.2060G>T p.G687V | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- USP32 | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VAX1 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 18/397 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- VPS45 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 66/503 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VSTM2B | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2
- WDR17 | c.2517G>T p.M839I | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- ZMAT1 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF148 | c.2002A>T p.R668* | Nonsense Mutation (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
- ZNF283 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF436 | c.741G>C p.E247D | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2
- ZNF549 | c.452A>G p.Q151R (on ENST00000376233 / NM_001199295.2; = p.Q138R on NM_153263.2) | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- ZNF711 | c.712G>T p.G238W | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- ZNF711 | c.1598A>G p.Y533C | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- ZSCAN26 | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2
- ADGRF4 | c.129C>A p.P43= | Silent (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2
- ANXA8 | c.630C>T p.A210= | Silent (SNP) | VAF 17/302 reads (6%) | called by muse, mutect2
- BEND4 | c.1492C>A p.R498= | Silent (SNP) | VAF 24/406 reads (6%) | catalogued as COSV101549706; called by muse, mutect2
- BOD1 | c.189C>T p.G63= | Silent (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2
- C12orf40 | c.597C>A p.S199= | Silent (SNP) | VAF 20/288 reads (7%) | catalogued as COSV61132339; called by muse, mutect2
- CASS4 | c.216G>T p.T72= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV64385768; called by muse, mutect2, varscan2
- CCNB3 | c.1572G>T p.L524= | Silent (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- CD6 | c.1374C>A p.T458= | Silent (SNP) | VAF 16/161 reads (10%) | called by muse, mutect2, varscan2
- CILP2 | c.1752G>T p.L584= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- COLGALT2 | c.1503C>A p.V501= | Silent (SNP) | VAF 32/462 reads (7%) | catalogued as COSV62300588; called by muse, mutect2
- CT47B1 | c.480C>A p.P160= | Silent (SNP) | VAF 17/277 reads (6%) | called by muse, mutect2
- CTNNA2 | c.909G>A p.L303= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV100782370; called by muse, mutect2, varscan2
- CTNNA3 | c.858G>T p.L286= | Silent (SNP) | VAF 26/242 reads (11%) | called by muse, varscan2
- DISC1 | c.1524G>T p.V508= | Silent (SNP) | VAF 65/359 reads (18%) | called by muse, mutect2, varscan2
- DOT1L | c.300G>T p.T100= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as COSV67109283; called by muse, mutect2, varscan2
- DTD2 | c.93C>T p.V31= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs1308132896, COSV60427979; called by muse, mutect2, varscan2
- EBF2 | c.1152A>G p.P384= | Silent (SNP) | VAF 26/314 reads (8%) | called by muse, mutect2
- ETV1 | c.762G>C p.L254= | Silent (SNP) | VAF 79/315 reads (25%) | catalogued as rs374017410; called by muse, mutect2, varscan2
- FANCM | c.4017A>T p.T1339= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV57505410; called by muse, mutect2, varscan2
- FBLN1 | c.1467C>A p.T489= | Silent (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- FBXW5 | c.1584G>A p.T528= | Silent (SNP) | VAF 26/338 reads (8%) | catalogued as rs578184749; called by muse, mutect2
- FGA | c.2199G>T p.G733= | Silent (SNP) | VAF 30/314 reads (10%) | called by muse, mutect2
- FSIP2 | c.18162A>T p.A6054= | Silent (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- GAREM2 | c.1449G>A p.L483= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs757117763; called by muse, varscan2
- GCK | c.129C>A p.R43= | Silent (SNP) | VAF 95/414 reads (23%) | catalogued as COSV61752581; called by muse, mutect2, varscan2
- GLUD2 | c.807C>A p.I269= | Silent (SNP) | VAF 26/272 reads (10%) | called by muse, mutect2
- GPR88 | c.987C>A p.S329= | Silent (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- GPX5 | c.192C>A p.I64= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as COSV101297282; called by muse, mutect2
- IGKV2D-29 | c.327G>A p.G109= | Silent (SNP) | VAF 33/292 reads (11%) | catalogued as rs554799243; called by muse, mutect2, varscan2
- ITIH3 | c.1932C>A p.P644= | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as rs1431448141; called by muse, mutect2, varscan2
- KCNA6 | c.327G>C p.P109= | Silent (SNP) | VAF 8/175 reads (5%) | called by muse, mutect2
- KCNT2 | c.1182A>G p.S394= | Silent (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- KIF19 | c.57G>T p.R19= | Silent (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- KIF1A | c.2790G>A p.G930= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2, varscan2
- LANCL3 | c.1080T>C p.S360= | Silent (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2
- LMNA | c.1359G>T p.R453= | Silent (SNP) | VAF 16/350 reads (5%) | catalogued as rs1321318572, COSV61543822; called by muse, mutect2
- LNX2 | c.1683G>T p.A561= | Silent (SNP) | VAF 56/480 reads (12%) | called by muse, varscan2
- MAGEA1 | c.783C>T p.R261= | Silent (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- MKRN2 | c.564G>T p.L188= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- MKRN3 | c.1335T>A p.L445= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV58811788; called by muse, mutect2
- MROH2B | c.4374C>G p.V1458= | Silent (SNP) | VAF 25/188 reads (13%) | called by muse, mutect2, varscan2
- MUC7 | c.318G>T p.V106= | Silent (SNP) | VAF 43/425 reads (10%) | called by muse, mutect2, varscan2
- NCCRP1 | c.660G>T p.G220= | Silent (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- NCOR1 | c.2271G>T p.T757= | Silent (SNP) | VAF 28/432 reads (6%) | catalogued as COSV51961413; called by muse, mutect2
- NEMF | c.30C>T p.L10= | Silent (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- NPIPB6 | c.1128G>A p.R376= | Silent (SNP) | VAF 38/599 reads (6%) | catalogued as rs762122986; called by muse, mutect2
- NXF3 | c.1128G>T p.L376= | Silent (SNP) | VAF 45/210 reads (21%) | called by muse, mutect2, varscan2
- OOSP2 | c.342C>T p.T114= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- OR1N2 | c.798A>G p.P266= | Silent (SNP) | VAF 42/554 reads (8%) | called by muse, mutect2
- OR2W3 | c.139C>T p.L47= | Silent (SNP) | VAF 15/355 reads (4%) | called by muse, mutect2
- OR56A5 | c.885T>C p.Y295= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1839G>T p.G613= | Silent (SNP) | VAF 37/267 reads (14%) | called by muse, mutect2, varscan2
- PDPR | c.2397C>T p.T799= | Silent (SNP) | VAF 35/450 reads (8%) | catalogued as COSV55355814; called by muse, mutect2
- PHLDB2 | c.1704A>T p.L568= | Silent (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- POU6F2 | c.1545C>T p.P515= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs774680072; called by muse, mutect2, varscan2
- PRKG1 | c.1203G>T p.T401= | Silent (SNP) | VAF 9/186 reads (5%) | catalogued as COSV64772066; called by muse, mutect2
- PSMD6 | c.99A>T p.G33= | Silent (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2
- RBP3 | c.3741G>T p.L1247= | Silent (SNP) | VAF 21/154 reads (14%) | called by muse, mutect2, varscan2
- RELN | c.745C>A p.R249= | Silent (SNP) | VAF 81/440 reads (18%) | catalogued as COSV58990404; called by muse, mutect2, varscan2
- RGPD3 | c.3537C>G p.P1179= | Silent (SNP) | VAF 14/577 reads (2%) | called by muse, mutect2
- RNF31 | c.2376G>T p.R792= | Silent (SNP) | VAF 30/288 reads (10%) | catalogued as COSV100141522; called by muse, mutect2
- RTL9 | c.63C>A p.P21= | Silent (SNP) | VAF 17/232 reads (7%) | catalogued as COSV71826175; called by muse, mutect2
- SLC12A3 | c.501C>A p.G167= | Silent (SNP) | VAF 34/313 reads (11%) | called by muse, mutect2, varscan2
- SLC44A5 | c.453C>A p.T151= | Silent (SNP) | VAF 11/187 reads (6%) | called by muse, mutect2
- SORCS3 | c.1422C>T p.A474= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs1324164101; called by muse, mutect2
- SPEG | c.330C>A p.A110= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs1226550372; called by muse, mutect2, varscan2
- TIMELESS | c.2887C>T p.L963= | Silent (SNP) | VAF 32/207 reads (15%) | called by muse, mutect2, varscan2
- TP73 | c.345C>T p.I115= | Silent (SNP) | VAF 20/376 reads (5%) | catalogued as rs1276905108; called by muse, mutect2
- TRAPPC6A | c.135C>T p.G45= (on ENST00000585934 / NM_001270891.2; = p.G59= on NM_024108.3) | Silent (SNP) | VAF 20/183 reads (11%) | called by muse, mutect2, varscan2
- UGT1A10 | c.792C>A p.P264= | Silent (SNP) | VAF 22/148 reads (15%) | called by muse, mutect2, varscan2
- UNC5C | c.2031G>T p.A677= | Silent (SNP) | VAF 28/386 reads (7%) | catalogued as COSV101497921; called by muse, mutect2
- USH2A | c.8220C>A p.V2740= | Silent (SNP) | VAF 13/291 reads (4%) | called by muse, mutect2
- VPS53 | c.1761G>T p.L587= (on ENST00000571805 / NM_001366253.2; = p.L558= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/325 reads (15%) | called by muse, mutect2, varscan2
- WDFY4 | c.2757G>T p.P919= | Silent (SNP) | VAF 18/313 reads (6%) | called by muse, mutect2
- WNK1 | c.75C>T p.P25= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as rs1219150253; called by muse, mutect2
- XPO6 | c.441G>A p.L147= | Silent (SNP) | VAF 23/188 reads (12%) | catalogued as rs756637169; called by muse, mutect2, varscan2
- ZNF679 | c.930C>T p.S310= | Silent (SNP) | VAF 40/244 reads (16%) | catalogued as rs758424385, COSV99738937; called by muse, mutect2, varscan2
- AGPAT4 | c.348+4985C>T | Intron (SNP) | VAF 9/177 reads (5%) | catalogued as rs1234066158; called by muse, mutect2
- ANKRD26P1 | n.62A>G | RNA (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- ARHGAP33 | c.1943-322G>T | Intron (SNP) | VAF 32/259 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916403 C>A | 5'Flank (SNP) | VAF 5/34 reads (15%) | catalogued as rs1437349822; called by muse, mutect2, varscan2
- ASTN2 | c.*321G>T | 3'UTR (SNP) | VAF 27/401 reads (7%) | called by muse, mutect2
- BLACE | n.1668G>T | RNA (SNP) | VAF 32/267 reads (12%) | called by muse, mutect2, varscan2
- BLOC1S2 | c.-7del | 5'UTR (DEL) | VAF 7/56 reads (13%) | called by pindel, varscan2
- C4orf50 | c.-1294C>G | 5'UTR (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- CDH8 | c.1536+24G>T | Intron (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- CEACAM6 | c.-6G>C | 5'UTR (SNP) | VAF 12/142 reads (8%) | catalogued as COSV99555499; called by muse, mutect2
- CSH1 | c.457-33C>G | Intron (SNP) | VAF 96/452 reads (21%) | called by muse, mutect2, varscan2
- CYP46A1 | c.282+3590T>A | Intron (SNP) | VAF 37/347 reads (11%) | called by muse, mutect2, varscan2
- DCP1B | c.319+2099C>T | Intron (SNP) | VAF 32/318 reads (10%) | called by muse, mutect2, varscan2
- DTNA | c.604-19G>T | Intron (SNP) | VAF 22/225 reads (10%) | called by muse, mutect2
- EIF2B5 | c.1326+42G>T | Intron (SNP) | VAF 41/315 reads (13%) | called by muse, mutect2, varscan2
- ELF4 | c.-34G>T | 5'UTR (SNP) | VAF 25/334 reads (7%) | catalogued as COSV100257119, COSV100257589; called by muse, mutect2
- ERC1 | c.3024+2160T>A | Intron (SNP) | VAF 40/240 reads (17%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009421 C>G | 5'Flank (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- FAM172BP | n.578C>A | RNA (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- FYN | c.862+514G>T | Intron (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- GDAP1 | c.*1544G>T | 3'UTR (SNP) | VAF 30/210 reads (14%) | called by muse, mutect2, varscan2
- GDI2 | c.45+1292A>T | Intron (SNP) | VAF 43/274 reads (16%) | called by muse, mutect2, varscan2
- HNF4A-AS1 | n.356+1388G>A | Intron (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- KRT8P11 | n.861G>T | RNA (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- LINC00955 | n.692G>T | RNA (SNP) | VAF 28/458 reads (6%) | called by muse, mutect2
- LINC01036 | n.105C>A | RNA (SNP) | VAF 16/309 reads (5%) | called by muse, mutect2
- LITAF | c.*443C>T | 3'UTR (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- MAN1B1 | c.*527T>G | 3'UTR (SNP) | VAF 22/346 reads (6%) | called by muse, mutect2
- MBD1 | c.793-153G>T | Intron (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- MBNL1 | c.174+40250G>T | Intron (SNP) | VAF 18/310 reads (6%) | catalogued as rs1377528270; called by muse, mutect2
- MIR518A1 | n.45A>G | RNA (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2
- MRPL21 | c.553+214C>G | Intron (SNP) | VAF 5/29 reads (17%) | called by muse, varscan2
- MRPL21 | c.553+213C>A | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, varscan2
- MYL2 | c.354-42C>A | Intron (SNP) | VAF 22/468 reads (5%) | called by muse, mutect2
- NME9 | c.*3T>C | 3'UTR (SNP) | VAF 39/228 reads (17%) | called by muse, mutect2, varscan2
- NUDT4 | chr12:93377579 T>C | 5'Flank (SNP) | VAF 31/384 reads (8%) | catalogued as rs1405111072; called by muse, mutect2
- OPRK1 | c.258-7732G>C | Intron (SNP) | VAF 8/65 reads (12%) | catalogued as COSV55573982; called by muse, mutect2
- OR2W5 | n.835C>A | RNA (SNP) | VAF 28/424 reads (7%) | catalogued as rs1439750499; called by muse, mutect2
- OSR2 | c.-114-492C>G | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- OVCH1 | chr12:29423246 G>T | 3'Flank (SNP) | VAF 22/332 reads (7%) | called by muse, mutect2
- PADI4 | c.340+572G>T | Intron (SNP) | VAF 30/176 reads (17%) | catalogued as rs1255256055; called by muse, mutect2, varscan2
- PKD1L2 | n.959C>A | RNA (SNP) | VAF 5/45 reads (11%) | called by mutect2, varscan2
- PRPF38A | c.*60G>A | 3'UTR (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- PTPN7 | chr1:202160612 G>A | 5'Flank (SNP) | VAF 18/142 reads (13%) | catalogued as rs1312823280; called by muse, mutect2, varscan2
- PUS1 | c.441+485G>T | Intron (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- RAB40A | c.-2C>A | 5'UTR (SNP) | VAF 8/50 reads (16%) | catalogued as rs1473513586; called by muse, varscan2
- RANBP17 | c.2776+49G>T | Intron (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- RNGTT | chr6:88965734 G>T | 5'Flank (SNP) | VAF 26/227 reads (11%) | called by muse, mutect2, varscan2
- RNU6-713P | chr12:40550502 G>T | 3'Flank (SNP) | VAF 17/131 reads (13%) | catalogued as rs1019850207; called by muse, mutect2, varscan2
- RPL36A | chrX:101390974 G>T | 5'Flank (SNP) | VAF 30/180 reads (17%) | called by muse, mutect2
- RPL36A | chrX:101390976 G>T | 5'Flank (SNP) | VAF 28/183 reads (15%) | called by muse, mutect2
- SINHCAF | c.-21+1035G>A | Intron (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- SLURP2 | c.*127C>A | 3'UTR (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- SYNPO2L | c.*1703G>A | 3'UTR (SNP) | VAF 19/306 reads (6%) | called by muse, mutect2
- TBX2 | c.1051+41G>T | Intron (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2
- TTN | c.10360+2302G>C | Intron (SNP) | VAF 16/330 reads (5%) | called by muse, mutect2
- TUBB7P | n.1179C>A | RNA (SNP) | VAF 23/295 reads (8%) | called by muse, mutect2
- VDR | chr12:47882733 C>A | 5'Flank (SNP) | VAF 28/247 reads (11%) | called by muse, mutect2, varscan2
- VNN3 | c.*50C>A | 3'UTR (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2
- XIAP | c.*5124G>T | 3'UTR (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
